Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7703, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7703-01A (Primary Tumor).

[page 1 of 2]
	Gross Description	Microscopic Description	Diagnosis Details	Comments	Formatted Path Report
					STOMACH TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Stomach Tumor size: 2.5 x 2 x 0.7 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Submucosa Lymph nodes: 0/4 positive for metastasis (Regional 0/4) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
ID	Laterality	Date of procurement
	Fundus	

Source: NCI Genomic Data Commons file 17d4c82e-8f71-495a-b17e-ad74282cbdc1 (TCGA-BR-7703.66C3A5CD-089D-4F2E-9610-8777807B2D59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).